Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A59F, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A59F-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3

Site: Endometrium C54.1

JW 4/2/13

Specimens Submitted:

- 1: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: Right hypogastric sentinel lymph node
- 3: Left external iliac sentinel lymph node
- 4: Right external iliac lymph node
- 5: Right para-aortic lymph node
- 6: Left para-aortic lymph node
- 7: Omentum

DIAGNOSIS:

1. Uterus, cervix, bilateral fallopian tubes and ovaries:

Tumor Type:

Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium
with homologous differentiation

Myometrial Invasion:

(>50%)

Measures 8 mm in maximum depth

Myometrium thickness measures 12 mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Identified

Endometrium:

Exhibits atrophy

Myometrium:

Exhibits adenomyosis

Exhibits multiple leiomyomata

Adnexa:

Right fallopian tube exhibits:hydrosalpinx

Right ovary exhibits:endometriosis, endosalpingiosis

Left fallopian tube exhibits:hydrosalpinx

Left ovary exhibits:endometriosis, tubal-ovary adhesion

Comment: The tumor has high proliferative index estimated at above 90%
by Ki-67 labeling. Immunostains for Synaptophysin and Chromogranin are
negative. There is no immunohistochemical support for neuroendocrine
differentiation.

** Continued on next page **

[page 2 of 2]
2. Sentinel lymph node, right hypogastric; excision:
- One benign lymph node (0/1) with endosalpingiosis
- Additional H/E stained sections and immunohistochemical stains for cytokeratins (AE1:AE3) show no evidence of metastatic tumor
3. Sentinel lymph node, left external iliac; excision:
- One benign lymph node with endosalpingiosis (0/1)
- Additional H/E stained sections and immunohistochemical stains for cytokeratins (AE1:AE3) show no evidence of metastatic tumor
4. Lymph node, right external iliac; excision:
- One benign lymph node (0/1)
5. Lymph node, right para-aortic; excision:
- One benign lymph node (0/1)
6. Lymph node, left para-aortic; excision:
- One benign lymph node (0/1)
7. Omentum, omentectomy:
- Benign fibroadipose tissue
- One benign lymph node (0/1)

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 969f83ac-46eb-4728-bd5c-57e0f2b514ed (TCGA-N5-A59F.5666CA72-D8E1-4781-8AE7-2321BDB57323.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).